Somatic mutation profile of tumor specimen TARGET-30-PAPBZI-01A (aliquot TARGET-30-PAPBZI-01A-01W) from TARGET case TARGET-30-PAPBZI, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 4.7 years (1,710 days).
Specimen TARGET-30-PAPBZI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a538f880-259b-43bf-abcb-7261c5705d5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPBZI-10A (Blood Derived Normal), aliquot TARGET-30-PAPBZI-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11734294-2d5d-4479-91c0-e0aaf86445d7

The open-access MAF lists 55 somatic variants for this specimen: 47 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 39, Silent 8, Nonsense Mutation 5, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 159/470 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121918453, CM013418, CM090463, COSV61004775, COSV61004869, COSV61006317; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A1CF | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 174/887 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.1); catalogued as COSV51008208; called by muse, mutect2, varscan2
- ABCA5 | c.3152C>A p.A1051D | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV67018840; called by muse, mutect2, varscan2
- AFG1L | c.215G>T p.C72F | Missense Mutation (SNP) | VAF 97/479 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.496); catalogued as COSV64554561; called by muse, mutect2, varscan2
- AHNAK | c.9368C>A p.P3123H | Missense Mutation (SNP) | VAF 109/497 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57227995; called by muse, mutect2, varscan2
- ALPK2 | c.4866G>T p.L1622F | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV64496577; called by muse, mutect2, varscan2
- CACNA1S | c.3376G>T p.A1126S | Missense Mutation (SNP) | VAF 71/448 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.345); catalogued as COSV62943147; called by muse, mutect2, varscan2
- CCDC88C | c.5545G>A p.A1849T | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374858033; called by muse, mutect2, varscan2
- COL4A1 | c.3937C>G p.P1313A | Missense Mutation (SNP) | VAF 145/471 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); catalogued as COSV65426036, COSV65431198; called by muse, mutect2, varscan2
- CYP27C1 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as rs754918379, COSV58868113; called by muse, mutect2, varscan2
- DNMT1 | c.1372C>A p.L458I | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.078); catalogued as COSV61583047; called by muse, mutect2, varscan2
- DOCK8 | c.299G>T p.C100F | Missense Mutation (SNP) | VAF 62/264 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV66635879; called by muse, mutect2, varscan2
- DSG2 | c.745A>T p.T249S | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.816); catalogued as COSV55202431; called by muse, mutect2, varscan2
- EHBP1L1 | c.2608G>A p.E870K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV58574797; called by muse, mutect2, varscan2
- ENPP2 | c.541A>T p.K181* | Nonsense Mutation (SNP) | VAF 34/207 reads (16%) | catalogued as COSV50033974; called by muse, mutect2, varscan2
- FBN2 | c.8227C>A p.Q2743K | Missense Mutation (SNP) | VAF 22/587 reads (4%) | SIFT tolerated (0.93); PolyPhen benign (0.121); catalogued as rs1227230008; called by muse, mutect2
- GBA2 | c.1728C>A p.Y576* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as COSV62306686, COSV62306722; called by muse, mutect2, varscan2
- GBF1 | c.4381C>T p.R1461C (on ENST00000369983 / NM_001377137.1; = p.R1460C on NM_004193.3) | Missense Mutation (SNP) | VAF 67/303 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64148542; called by muse, mutect2, varscan2
- GPC2 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs533621775, COSV52786311; called by mutect2, varscan2
- KDM5A | c.3219G>T p.V1073= | Splice Region (SNP) | VAF 17/139 reads (12%) | catalogued as COSV66995896; called by muse, mutect2, varscan2
- MDN1 | c.3710G>T p.S1237I | Missense Mutation (SNP) | VAF 49/279 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV65529262; called by muse, mutect2, varscan2
- METTL4 | c.587G>T p.C196F | Missense Mutation (SNP) | VAF 58/264 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV60604723; called by muse, mutect2, varscan2
- MUC16 | c.17746C>A p.Q5916K | Missense Mutation (SNP) | VAF 59/297 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV67489484; called by muse, mutect2, varscan2
- NAV2 | c.5362C>A p.Q1788K (on ENST00000396087 / NM_001244963.2; = p.Q1732K on NM_145117.5) | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.185); catalogued as rs1009660563, COSV60664456; called by muse, mutect2, varscan2
- OR8H3 | c.703C>A p.Q235K | Missense Mutation (SNP) | VAF 72/353 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV57910268, COSV57911241; called by muse, mutect2, varscan2
- PACSIN3 | c.51G>T p.W17C | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54067726; called by muse, mutect2, varscan2
- PBX4 | c.818G>T p.G273V | Missense Mutation (SNP) | VAF 98/530 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.619); catalogued as COSV52063856; called by muse, mutect2, varscan2
- PLEKHA7 | c.3343G>T p.G1115* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as COSV60580963; called by muse, mutect2, varscan2
- PTPRT | c.735C>A p.H245Q | Missense Mutation (SNP) | VAF 39/202 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.157); catalogued as COSV62013701; called by muse, mutect2, varscan2
- RPS6KA3 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 71/132 reads (54%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV65389261; called by muse, mutect2, varscan2
- SDHA | c.372C>A p.Y124* | Nonsense Mutation (SNP) | VAF 19/108 reads (18%) | catalogued as COSV53766673, COSV53773057; called by muse, mutect2, varscan2
- SH3TC2 | c.3712C>A p.L1238M | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757548779, COSV60467355; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A20 | c.291G>T p.K97N | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59804496, COSV59804591; called by muse, mutect2, varscan2
- SLC5A10 | c.1118T>C p.M373T (on ENST00000395645 / NM_001042450.4; = p.M389T on NM_152351.5) | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV58761595; called by muse, mutect2, varscan2
- SPEF2 | c.1930G>A p.V644I | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV61552927; called by muse, mutect2, varscan2
- TDRKH | c.382C>A p.Q128K | Missense Mutation (SNP) | VAF 61/491 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.031); catalogued as COSV64316675; called by muse, mutect2, varscan2
- TUBGCP3 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56191005; called by muse, mutect2, varscan2
- UBAP2L | c.3088G>T p.A1030S | Missense Mutation (SNP) | VAF 114/776 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV55180283; called by muse, varscan2
- UBQLN1 | c.1273G>T p.A425S | Missense Mutation (SNP) | VAF 101/461 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV57409205; called by muse, mutect2, varscan2
- YME1L1 | c.397C>T p.Q133* (on ENST00000326799 / NM_139312.3; = p.Q76* on NM_014263.4) | Nonsense Mutation (SNP) | VAF 29/168 reads (17%) | catalogued as COSV58761308; called by muse, mutect2, varscan2
- ZNF470 | c.946C>A p.Q316K | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV57970505; called by muse, mutect2, varscan2
- ZNF529 | c.916G>T p.D306Y | Missense Mutation (SNP) | VAF 146/320 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61900856, COSV61901919; called by muse, mutect2, varscan2
- ZNF646 | c.2009G>A p.R670Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as rs140188005; called by muse, mutect2, varscan2
- ZNF785 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV67876398; called by muse, varscan2
- FBXL13 | c.628_632del p.K210Yfs*34 | Frame Shift Del (DEL) | VAF 41/208 reads (20%) | called by mutect2, pindel*, varscan2*
- PRKACG | c.1035del p.K346Rfs*43 | Frame Shift Del (DEL) | VAF 31/103 reads (30%) | called by mutect2, pindel, varscan2
- PSG7 | c.635C>A p.A212E | Missense Mutation (SNP) | VAF 72/1414 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2
- ARVCF | c.2379C>T p.N793= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs184898905, COSV52890802; called by muse, mutect2, varscan2
- EHMT1 | c.75G>T p.L25= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV58380932; called by muse, mutect2, varscan2
- GMDS | c.603A>G p.A201= | Silent (SNP) | VAF 32/198 reads (16%) | catalogued as COSV66441015; called by muse, mutect2, varscan2
- HRNR | c.2100C>A p.G700= | Silent (SNP) | VAF 40/237 reads (17%) | catalogued as COSV64262197; called by muse, mutect2, varscan2
- ITIH2 | c.2010C>A p.A670= | Silent (SNP) | VAF 35/186 reads (19%) | catalogued as COSV64434956; called by muse, mutect2, varscan2
- ROM1 | c.859C>A p.R287= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as rs768652143, COSV53884403; called by muse, mutect2, varscan2
- SLC34A1 | c.1137C>A p.G379= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as COSV60998536; called by muse, mutect2, varscan2
- TBX19 | c.1119G>T p.V373= | Silent (SNP) | VAF 53/354 reads (15%) | catalogued as COSV63198328; called by muse, mutect2, varscan2
